Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6CS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6CS-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localisation: R frontal

Diagnosis: anaplastic astrocytoma (grade III WHO)

Name of Pathologist:

ICD-O-3

Astrocytoma, anaplastic 9401/3

Site: O6CFY Brain, supratentorial ^{NOx}
C71.0

path R Brain, frontal lobe
C71.1

gr 5/16/13

Primary, Tumor Site Discrepancy		

Source: NCI Genomic Data Commons file 4113e3e3-e32a-4e90-b6f3-1e6e04967f41 (TCGA-QH-A6CS.0C4238FC-0A3C-46B5-8FFF-08D66878521A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).